Somatic mutation profile of tumor specimen 0DA69G from CCDI case PBBJIB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.6 years (6,067 days).
Specimen 0DA69G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea309729-4c55-47ee-9813-9c1136070d18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA69C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d6ef952-2e15-4a5e-98e5-20a63ad63b44

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSPG2 | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 33/566 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs370645398; called by muse, mutect2
- CCDC105 | c.1152A>C p.K384N | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.257); called by muse, mutect2
- KDM3B | c.1733A>C p.D578A | Missense Mutation (SNP) | VAF 48/759 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.027); called by muse, mutect2
- SWAP70 | c.1676C>G p.T559S | Missense Mutation (SNP) | VAF 54/1413 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.918); called by muse, mutect2
- VHLL | c.72G>A p.E24= | Silent (SNP) | VAF 74/509 reads (15%) | called by muse, mutect2, varscan2
- DIS3L | c.2201+70T>C | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- HCAR1 | c.-24C>T | 5'UTR (SNP) | VAF 64/634 reads (10%) | called by muse, mutect2
- HHIPL1 | c.1730+633G>T | Intron (SNP) | VAF 73/780 reads (9%) | called by muse, mutect2
